Somatic mutation profile of tumor specimen TARGET-10-PATTHR-09A (aliquot TARGET-10-PATTHR-09A-01D) from TARGET case TARGET-10-PATTHR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,917 days).
Specimen TARGET-10-PATTHR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bb8223b-b218-4381-9f77-7504d0bb87b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PATTHR-10A (Blood Derived Normal), aliquot TARGET-10-PATTHR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b52a377-eae6-4efd-9655-20b42d1a6657

The open-access MAF lists 31 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, In Frame Ins 1, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 96/215 reads (45%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- DNAI2 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 55/120 reads (46%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.912); catalogued as rs755972641, COSV56757330; called by muse, mutect2, varscan2
- ETV6 | c.197T>G p.V66G | Missense Mutation (SNP) | VAF 32/34 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67147957, COSV67148593; called by muse, varscan2
- GATA3 | c.857C>T p.A286V | Missense Mutation (SNP) | VAF 61/137 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60516362; called by muse, mutect2, varscan2
- JAK3 | c.2021T>C p.V674A | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV71685576; called by muse, mutect2, varscan2
- KLHL40 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as rs150228964, COSV55133147; called by muse, varscan2
- NOTCH1 | c.5027T>A p.V1676D | Missense Mutation (SNP) | VAF 42/106 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53026269; called by muse, varscan2
- POTEH | c.230A>C p.K77T | Missense Mutation (SNP) | VAF 60/279 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); catalogued as COSV58880901; called by muse, mutect2, varscan2
- RECQL5 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs192913858; called by muse, mutect2, varscan2
- SPTA1 | c.6889C>T p.R2297W | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs375016862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEK | c.2171C>A p.A724D | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.089); catalogued as COSV66234428; called by mutect2, varscan2
- UNC5D | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs775726745, COSV54776450; called by muse, mutect2, varscan2
- ZMIZ1 | c.509T>G p.V170G | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57891267; called by muse, mutect2, varscan2
- DSTYK | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.49); PolyPhen benign (0.005); called by muse, mutect2
- HIF1AN | c.700C>A p.H234N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNA1 | c.1055C>A p.A352D | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2
- LIMS2 | c.388_389insGGG p.R129_E130insG (on ENST00000355119 / NM_001161403.3; = p.R153_E154insG on NM_017980.4) | In Frame Ins (INS) | VAF 18/46 reads (39%) | called by mutect2, pindel, varscan2
- NCOA2 | c.4154G>T p.S1385I | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2
- NSD3 | c.4115G>T p.S1372I | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- PANK4 | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 28/28 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.301); called by muse, mutect2
- POLR1H | c.118C>A p.R40S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.813); called by muse, mutect2
- SETD5 | c.1240C>A p.Q414K | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); called by muse, mutect2
- TAAR2 | c.59del p.K20Rfs*45 | Frame Shift Del (DEL) | VAF 54/135 reads (40%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.263C>A p.A88D | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2
- CCDC157 | c.648G>A p.T216= | Silent (SNP) | VAF 54/121 reads (45%) | catalogued as rs200816093; called by muse, mutect2, varscan2
- CD180 | c.435G>T p.V145= | Silent (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2, varscan2
- FAM71F1 | c.486C>T p.R162= | Silent (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- SCG2 | c.196C>A p.R66= | Silent (SNP) | VAF 26/57 reads (46%) | catalogued as rs1249747406, COSV59538877; called by muse, mutect2, varscan2
- SOCS3 | c.633G>T p.P211= | Silent (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2
- ZNF404 | c.648A>G p.E216= | Silent (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- MUC19 | n.5361C>T | RNA (SNP) | VAF 31/67 reads (46%) | catalogued as rs1216831752; called by muse, mutect2, varscan2
